Somatic mutation profile of tumor specimen 0DX0QX from CCDI case PBCPBA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 22.5 years (8,200 days).
Specimen 0DX0QX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37316366-3737-41c1-9d8a-5b5eff4ec33b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX0Q2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/523b7c4b-07ee-4f42-bdb5-e495cb447ba4

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 178/650 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- TP53 | c.757A>C p.T253P | Missense Mutation (SNP) | VAF 186/692 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52783299, COSV52873550, COSV52906834; called by muse, varscan2
- CCT8 | chr21:29073659 G>A | 5'Flank (SNP) | VAF 40/256 reads (16%) | catalogued as rs901290156; called by muse, varscan2
- PEX5L | c.22-2404A>G | Intron (SNP) | VAF 119/718 reads (17%) | catalogued as rs1031116769; called by muse, varscan2
